Gene-level copy-number profile of tumor specimen C3N-05108-04 from CPTAC case C3N-05108, project CPTAC-3 (Skin — Nevi and Melanomas). Sex at birth: female; Vital status: Alive; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; AJCC pathologic stage: Stage IIIC; Age at diagnosis: 73.9 years (26,980 days).
Specimen C3N-05108-04: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Solid Tissue; Biospecimen anatomic site: Trunk; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 99e456bd-78d3-4761-b82b-d5787de98ec4.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator C3N-05108-31 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,230 have no estimate.
https://portal.gdc.cancer.gov/files/bc4ff93f-b3c4-49f7-984c-bb8bd7215c44

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 213; copy number 1: 9,806; copy number 2: 40,012; copy number 3: 8,004; copy number 4: 347; copy number 6: 11.

Homozygous deletions (total copy number 0; autosomes only): 213 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr7:38,239,580–38,340,998, 16 genes: TRGC2, TRGJP2, TRGC1, TRGJ1, TRGJP, TRGJP1, TRGV11, TRGVB, TRGV10, AC006033.1, TRGV9, TRGVA, AC006033.2, TRGV8, TRGV7, TRGV6.
- chr7:38,345,030–38,354,517, 3 genes (within-gene range 0–3): TRGV5P, TRGV5, TRGV4.
- chr10:131,901,008–133,778,699, 77 genes (broad region; genes not listed).
- chr14:21,841,240–22,552,156, 117 genes (within-gene range 0–2) (broad region; genes not listed).

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 11 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr16:11,555–57,669, 8 genes, copy number 6: DDX11L10, WASH4P, MIR6859-4, Z84723.1, WASIR2, IL9RP3, POLR3K, SNRNP25.
- chr21:46,635,595–46,691,226, 3 genes, copy number 6: PRMT2, DSTNP1, RPL23AP4.

Autosomal genes at a single copy (total copy number 1): 7,462. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
